Surgical pathology report (de-identified scan), TCGA case TCGA-21-A5DI, project TCGA-LUSC (Lung Squamous Cell Carcinoma), tissue source site Fox Chase Cancer Center, specimen TCGA-21-A5DI-01A (Primary Tumor).

[page 1 of 4]
SPECIMEN:
SURGICAL PATHOLOGY REPORT

DOB:
Sex: M
Location:
Date Collected:
Date Received
Physician
Copy To:
Clinical History/Diagnosis: Right lower lobe lung mass

ICD-0-3
Carcinoma, squamous
cell NOS 8070/3
Site (R) Lung, lower lobe
6343
JW 5/24/13

Source of Specimen(s):
1: level 9 lymph node
2: portion of right level 11 lymph node
3: right lower lobe of lung
4: level 4 lymph nodes
5: level 7 lymph nodes

Gross Description:
Received in five parts.
Source of Tissue: 1. Labeled # 1, "level 9 lymph node"

Gross Description: Received fresh in a container labeled "level 9 lymph node". It consists of a single ovoid rubbery gray lymph node measuring 2.4 x 1.4 x 1.3 cm. Sections disclose a tan-gray cut surface. Entirely submitted in 1A.

Source of Tissue: 2. Labeled # 2, "portion of right level 11 lymph node"

Gross Description: Received fresh in a container labeled "portion of right level 11 lymph node". It consists of three grayish black tissue fragments measuring respectively 0.5, 0.8 and 1.0 cm. The larger node is bisected. All four fragments are submitted in 2A.

Source of Tissue: 3. Labeled # 3, "right lower lobe"

Frozen Section Diagnosis: 3FS- NO TUMOR SEEN AT BRONCHIAL MARGIN PER

Gross Description: Received fresh for frozen section consultation in a container labeled "right lower lobe". It consists of a 180 gram right lower lobe of lung measuring 15.0 x 12.0 x 6.0 cm. The bronchial margin was procured for frozen section and the residue is in 3FS. Also at the hilum are multiple tan firm nodules measuring up to 2.0 cm. The nodules are consistent with lymph nodes with marked and anthracotic changes and possible metastatic disease. The vascular and bronchial margins are unremarkable. The bronchial tree is opened and is likewise unremarkable. There is some pleura adjacent to the

Prior lymphoma, treatment
unknown by JSS.

[page 2 of 4]
hilum having a white thickened cobblestone appearance measuring 2.0 x 2.0 cm. This area will be additionally sampled for histological impression and comes to within 1.8 cm from the margin. Posterior inferior on the lung, partially involving the diaphragmatic surface is a large area of pleural puckering. This area is received partially sectioned disclosing a large tan mass measuring 4.0 x 4.0 x 3.8 cm. The tumor comes to within 5.8 cm from the margin. Sections show a central ragged cavity containing necrotic debris. Elsewhere, the pleura is tan-pink, spongy and no additional lesions or masses are found. Representative sections are submitted in 3A-I.

Designation of Sections: 3A- vascular margins, 3B-3D- multiple single hilar and peribronchial lymph nodes, 3E- thickened pleura with possible tumor studding adjacent to hilum, 3F-3H- right lower lobe tumor, 3I- uninvolved right lower lobe lung tissue

Source of Tissue: 4. Labeled # 4, "level 4 lymph nodes"

Gross Description: Received fresh in a container labeled "level 4 lymph nodes". It consists of a single gray firm to rubbery lymph node measuring 1.2 x 1.0 x 0.8 cm. It is bisected disclosing a tan firm cut surface. Entirely submitted in 4A.

Source of Tissue: 5. Labeled # 5, "level 7 lymph nodes"

Gross Description: Received fresh in a container labeled "level 7 lymph nodes". It consists of two tan rubbery nodules measuring respectively 3.2 x 2.5 x 1.5 and 5.0 x 4.0 x 3.0 cm. The smaller node is sectioned disclosing a tan to grayish black cut surface. The larger portion of tissue is consistent with a few matted nodes ranging from 1.0 up to 4.0 cm. Sections disclose predominantly tan homogeneous cut surfaces. Representative sections are submitted in 5A-G.

Designation of Sections: 5A-5B- single lymph node, 5C-5G- multiple sections of single nodes [from large matted mass of nodes]

Final Diagnosis:

****AMENDED REPORT****

This amended report is issued to correct the staging in the template to pTNM: T2N0Mx.

1. Level 9 lymph node, biopsy:

- No evidence of metastatic carcinoma in one lymph node (0/1).
- Small lymphocytic lymphoma present, see note.

[page 3 of 4]
2. Portion of right level 11 lymph node, biopsy:
- No evidence of metastatic carcinoma in four lymph nodes (0/4).
3. Lung, right lower lobe, lobectomy:
- Invasive squamous cell carcinoma, 4 cm, poorly differentiated.
- The tumor does not involve the visceral pleura.
- Lymphovascular space invasion is not seen.
- The pleural, bronchial and vascular margins are free of tumor.
- No metastatic carcinoma is seen in eleven peribronchial lymph nodes (0/11).
4. Level 4 lymph nodes, biopsy:
- No evidence of metastatic carcinoma in one lymph node (0/1).
- Small lymphocytic lymphoma present.
5. Level 7 lymph nodes, biopsy:
- No evidence of metastatic carcinoma in multiple matted lymph nodes.
- Small lymphocytic lymphoma present.
- pT2N0Mx

Note: The lymph nodes show effacement of the normal architecture by small lymphocytes. The tumor lymphocytes are positive for CD20 and CD23. The lymphocytes are negative for CD10, CD3 and cyclinD1. The CD5 seems to be following the pattern of the CD3. These findings are consistent with small lymphocytic lymphoma.

These tests were developed and their performance characteristics determined by the immunohistochemistry laboratory at the

These tests have not been cleared or approved by the U.S. Food and Drug Administration. The FDA has determined that such clearance or approval is not necessary. These tests are used for clinical purposes. They should not be regarded as investigational or for research. This laboratory is certified under the Clinical Laboratory Improvement Amendments of 1998 (CLIA) as qualified to perform high complexity clinical testing.

Amendments

Amended:

Reason:

Previous Signout Date:

LUNG TEMPLATE

Specimen Type

Lobectomy

[page 4 of 4]
Laterality
Right

Tumor Site
Lower lobe

Tumor Size
Greatest dimension: 4 cm (T1 if ≤ 3.0 cm; otherwise T2)

Histologic Type
Squamous cell carcinoma

Histologic Grade
Poorly differentiated

Extension of Tumor
Carcinoma does not involve visceral pleura (T1 unless > 3.0 cm T2)/

Venous (Large Vessel) Invasion
Absent

Arterial (Large Vessel) Invasion
Absent

Margins
Margins uninvolved by invasive carcinoma

Regional Lymph Nodes
>15 regional lymph nodes examined
No regional lymph node metastasis

pTNM: T2N0Mx

Source: NCI Genomic Data Commons file 5757be0b-e416-4fe7-80bc-77f4ef442ac6 (TCGA-21-A5DI.54DCDFE6-FF29-4549-ACB2-420165FF391B.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).